Somatic mutation profile of tumor specimen BA2078D (aliquot aq-BA2078D) from BEATAML1.0 case 2062, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.6 years (23,599 days).
Specimen BA2078D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b42049b-1f58-4fce-ae52-5cbed8b0efc1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2138D (Solid Tissue Normal), aliquot aq-BA2138D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b345a8b-8680-431c-8a56-b2e5bab7db09

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GLP2R | c.61G>A p.V21I | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs745596472; called by muse, mutect2, varscan2
- MGA | c.221G>A p.G74E | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as rs1300663514; called by muse, mutect2
- RLN3 | c.117C>G p.F39L | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54598897; called by muse, mutect2
- SBNO2 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs1248049242; called by mutect2, varscan2
- ADGRB1 | c.1371C>A p.N457K | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CDH11 | c.1841G>T p.G614V | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- PLCH1 | c.3072G>T p.K1024N (on ENST00000340059 / NM_001130960.2; = p.K1016N on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); called by muse, mutect2
- SRCAP | c.475C>A p.R159= | Silent (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- KLK2 | c.630+22C>A | Intron (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2
